TCGA case TCGA-OD-A75X — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Bronchus and lung; Tissue source site: Saint Mary's Health Care. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ef9f1829-0eed-47b3-9d44-06d0a8bb2bfb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 49 years; Vital status: Dead; Days to death: 9,061 days (24.8 years).

Diagnoses (6)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C34.1; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Upper lobe, lung; Classification of tumor: metastasis; Age at diagnosis: 72.7 years (26,540 days); Days to diagnosis: 8,630 days (23.6 years); Prior treatment: No; Days to last follow up: 9,061 days (24.8 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Sites of involvement: Skin, Trunk.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 49.0 years (17,910 days); Year of diagnosis: 1989; AJCC staging edition: 3rd; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M0; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
4. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Brain, NOS. Age at diagnosis: 73.6 years (26,897 days); Days to diagnosis: 8,987 days (24.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 9,011 days (24.7 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.
5. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Stomach, NOS. Age at diagnosis: 73.8 years (26,954 days); Days to diagnosis: 9,044 days (24.8 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
6. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 73.8 years (26,955 days); Days to diagnosis: 9,045 days (24.8 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (5 entries)
- Days to follow up: 8,966 days (24.5 years); Disease response: Tumor Free.
- Day 8,987 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 8,987 days (24.6 years).
- Day 9,044 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Stomach, NOS; Days to progression: 9,044 days (24.8 years).
- Day 9,045 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 9,045 days (24.8 years).
- Days to follow up: 9,061 days (24.8 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 103 kg; Height: 182 cm; BMI: 31.1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-OD-A75X-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 390 mg.
  Slide TCGA-OD-A75X-06A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-OD-A75X-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-OD-A75X-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Radiation therapy to primary: No; Primary location: Distant Metastasis; Metastatic tumor site: left upper lung lobe; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Subsequent known primaries: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 9,061 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 9,061 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 8,987 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-OD-A75X-06A-12D-A32M-01): tumor purity 0.83, ploidy 3.69, whole-genome doublings 1.
